Somatic mutation profile of tumor specimen 0DP0N6 from CCDI case PBCDAZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 17.3 years (6,305 days).
Specimen 0DP0N6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc34b21e-0cd8-4f8b-9653-4f4153ee3b62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP0MS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a08b6628-8d74-4a78-9e2e-a0d3bc376c2a

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.2739-1G>T p.X913_splice | Splice Site (SNP) | VAF 304/728 reads (42%) | catalogued as rs943468139, COSV101008879, COSV65523972; called by muse, varscan2
- FBN1 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 736/1792 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs746073643, COSV57311022, COSV57328035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 58/918 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs780573092; called by muse, mutect2
- FRAS1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 352/878 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs374688692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSAMP | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 634/1449 reads (44%) | catalogued as rs1314865643, COSV100373041; called by muse, mutect2, varscan2
- RECQL4 | c.3393+7G>A | Splice Region (SNP) | VAF 199/539 reads (37%) | catalogued as rs751080188; called by muse, mutect2, varscan2
- ANKRD20A1 | c.81C>A p.Y27* | Nonsense Mutation (SNP) | VAF 119/376 reads (32%) | called by muse, mutect2, varscan2
- BCL11B | c.2272G>C p.D758H (on ENST00000357195 / NM_001282237.2; = p.D687H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/468 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCDC60 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 139/2244 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2
- OR2V1 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 390/896 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- PGLYRP2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 30/778 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 58/1228 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- BCL11B | c.2271G>A p.G757= (on ENST00000357195 / NM_001282237.2; = p.G686= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 200/461 reads (43%) | called by muse, mutect2, varscan2
- ARL8A | c.*66C>T | 3'UTR (SNP) | VAF 136/257 reads (53%) | catalogued as rs983504546; called by muse, mutect2, varscan2
- ASIC4 | c.855+56A>T | Intron (SNP) | VAF 112/203 reads (55%) | called by muse, mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 30/901 reads (3%) | called by muse, mutect2
